Somatic mutation profile of tumor specimen ALCH-B1UE-TTP1-A (aliquot ALCH-B1UE-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1UE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 50.7 years (18,524 days).
Specimen ALCH-B1UE-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fa71261-7c7a-488b-87d3-c3c6a6a0eb68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1UE-NB1-A (Blood Derived Normal), aliquot ALCH-B1UE-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d123dc69-6b81-4350-bc8c-448302b7870d

The open-access MAF lists 202 somatic variants for this specimen: 143 protein-altering or splice-affecting, 40 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 40, Intron 11, Nonsense Mutation 10, Frame Shift Del 6, 5'UTR 2, In Frame Del 2, 5'Flank 2, Splice Site 2, Splice Region 2, RNA 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.810del p.F270Lfs*75 | Frame Shift Del (DEL) | VAF 57/329 reads (17%) | catalogued as rs1567548114, COSV52809003, COSV53009334; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACADL | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs149888279; called by muse, mutect2
- ANK3 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 41/306 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1395573055, COSV99782218; called by muse, mutect2, varscan2
- BDP1 | c.2810T>C p.I937T | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as rs1219149593; called by muse, mutect2, varscan2
- CFAP299 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 23/332 reads (7%) | catalogued as rs897912314; called by muse, mutect2
- CRYGB | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV53680821; called by muse, mutect2, varscan2
- DCDC2 | c.1117C>A p.L373I | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV65829288; called by muse, mutect2, varscan2
- DDC | c.1340G>T p.R447L | Missense Mutation (SNP) | VAF 36/405 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM077527, COSV63563400; called by muse, mutect2
- FAM135B | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV52715704, COSV99419747; called by muse, mutect2
- FANCA | c.4168-4C>G | Splice Region (SNP) | VAF 41/404 reads (10%) | catalogued as rs775180524; called by muse, mutect2, varscan2
- GART | c.1861A>T p.S621C | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs1319678385; called by muse, mutect2, varscan2
- GNL3L | c.1601C>A p.P534H | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs755079400, COSV60575344; called by mutect2, varscan2
- GPR158 | c.1832G>T p.R611L | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66271463; called by muse, mutect2, varscan2
- GSTA3 | c.449G>C p.G150A | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99274713; called by muse, mutect2
- HCFC2 | c.990G>T p.W330C | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57558854; called by muse, varscan2
- KCNH5 | c.1069G>C p.G357R | Missense Mutation (SNP) | VAF 44/424 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as rs1303471073; called by muse, mutect2
- KEAP1 | c.571G>C p.A191P | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50260766, COSV50261366; called by muse, mutect2, varscan2
- KLC3 | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 33/299 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67270496; called by muse, mutect2, varscan2
- KRTAP4-9 | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 47/477 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs770484140, COSV66949953; called by muse, mutect2, varscan2
- MBL2 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64759591; called by muse, mutect2, varscan2
- MET | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs200283364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRTFA | c.1679G>T p.R560L | Missense Mutation (SNP) | VAF 51/301 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV99053168; called by muse, mutect2, varscan2
- NXPH2 | c.545C>G p.S182C | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV55641550; called by muse, mutect2
- OR11L1 | c.215G>A p.W72* | Nonsense Mutation (SNP) | VAF 49/203 reads (24%) | catalogued as COSV100869458, COSV63313907; called by muse, mutect2, varscan2
- PCDHB8 | c.839A>G p.Y280C | Missense Mutation (SNP) | VAF 22/566 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554281035; called by muse, mutect2
- PCLO | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.145); catalogued as rs201699382; called by muse, mutect2
- PHKA2 | c.2586G>T p.K862N | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as COSV101176594; called by muse, mutect2, varscan2
- POU3F4 | c.94C>A p.R32S | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV104427747; called by muse, varscan2
- PPP1R9A | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as COSV56897530; called by muse, mutect2
- PTPN5 | c.39C>G p.H13Q | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs759114689; called by muse, mutect2
- SAMHD1 | c.1258A>G p.T420A | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs754153159; called by muse, mutect2, varscan2
- SCN7A | c.2053C>A p.L685I | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV69268784, COSV69269087; called by muse, mutect2, varscan2
- SEZ6L | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as COSV50658263; called by muse, mutect2, varscan2
- SLC44A5 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV63775863; called by muse, mutect2, varscan2
- SMUG1 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1296885820; called by muse, mutect2
- TBC1D22B | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65142268; called by muse, mutect2
- TEX55 | c.841C>A p.L281M | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.905); catalogued as COSV55212278; called by muse, mutect2, varscan2
- TPD52 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 46/662 reads (7%) | SIFT tolerated, low confidence (0.31); catalogued as rs1004541972; called by muse, mutect2
- TRPA1 | c.2738T>C p.L913P | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1355186822; called by muse, mutect2
- USH2A | c.5953G>A p.E1985K | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs150143291, CM153227; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UTP14A | c.2179C>A p.H727N | Missense Mutation (SNP) | VAF 29/334 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as rs866910927; called by muse, mutect2
- ZIC1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51553293; called by muse, mutect2
- ZNF585B | c.1169C>A p.A390D | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1411715192; called by muse, mutect2
- A1CF | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCA1 | c.2605G>T p.E869* | Nonsense Mutation (SNP) | VAF 34/334 reads (10%) | called by muse, mutect2, varscan2
- ABCB5 | c.181T>G p.C61G | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.662); called by muse, mutect2
- ACLY | c.3025G>T p.E1009* | Nonsense Mutation (SNP) | VAF 11/137 reads (8%) | called by muse, mutect2
- ACOXL | c.1049C>A p.T350N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2
- AFMID | c.752T>G p.F251C | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- AKAP8 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 28/269 reads (10%) | called by muse, mutect2, varscan2
- AMY2B | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.118); called by muse, mutect2
- AP3B1 | c.3022G>C p.A1008P | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.283); called by muse, mutect2
- ARMC5 | c.14A>G p.K5R | Missense Mutation (SNP) | VAF 27/374 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2
- ATXN1 | c.1814G>A p.S605N | Missense Mutation (SNP) | VAF 28/434 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2
- B3GNT7 | c.690C>G p.C230W | Missense Mutation (SNP) | VAF 54/400 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BEND5 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BPIFB3 | c.1361T>C p.L454P | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C3orf85 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD72 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 52/535 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- CNTNAP4 | c.1704G>T p.W568C | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL4A6 | c.381T>A p.N127K | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL6A6 | c.1702T>C p.Y568H | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.025); called by muse, mutect2
- COL6A6 | c.2387G>T p.C796F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CSMD3 | c.7349del p.P2450Qfs*14 (on ENST00000297405 / NM_001363185.1; = p.P2346Qfs*14 on NM_052900.3) | Frame Shift Del (DEL) | VAF 18/157 reads (11%) | called by mutect2, pindel, varscan2
- CSTF2 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DCAF8 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DZIP3 | c.2434C>T p.Q812* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- ERG | c.83G>T p.C28F | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ETNK1 | c.592C>G p.Q198E | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM228B | c.794A>T p.K265I | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.692); called by muse, mutect2
- FAT1 | c.13116G>T p.Q4372H | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- FLNA | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 46/462 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2
- FOLR1 | c.684C>G p.F228L | Missense Mutation (SNP) | VAF 143/348 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- GLE1 | c.1294C>G p.Q432E | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2
- GLYATL3 | c.557C>A p.S186Y | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GNAO1 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); called by muse, mutect2
- GOLM2 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 32/381 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- HLCS | c.1962A>C p.K654N | Missense Mutation (SNP) | VAF 25/298 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2
- IGFBP7 | c.402_413del p.A135_Q138del | In Frame Del (DEL) | VAF 24/190 reads (13%) | called by mutect2, pindel
- IGSF1 | c.2410C>A p.Q804K | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.089); called by muse, varscan2
- IQCH | c.1483T>C p.C495R | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- KATNAL2 | c.261del p.I89Lfs*24 (on ENST00000356157 / NM_001353899.1; = p.I17Lfs*24 on NM_031303.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | called by mutect2, pindel, varscan2
- KCNU1 | c.1349T>C p.L450P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- KIR3DL2 | c.1129C>A p.P377T | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.169); called by muse, mutect2
- KMT2D | c.6159del p.A2054Qfs*40 | Frame Shift Del (DEL) | VAF 16/184 reads (9%) | called by mutect2, pindel*
- LIF | c.19G>C p.G7R | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LMOD2 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- LONRF3 | c.937-1G>T p.X313_splice | Splice Site (SNP) | VAF 12/155 reads (8%) | called by muse, mutect2
- LTBP1 | c.1123G>T p.E375* (on ENST00000404816 / NM_206943.4; = p.E49* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 25/185 reads (14%) | called by muse, mutect2, varscan2
- MAG | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 53/422 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- MAP3K6 | c.3718A>C p.N1240H | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.191); called by muse, mutect2
- MED12 | c.5681A>T p.K1894M | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.996); called by muse, mutect2
- MGAM2 | c.4355A>G p.Q1452R | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.972); called by muse, mutect2
- MKKS | c.579C>A p.H193Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- NECAP1 | c.302-6C>T | Splice Region (SNP) | VAF 27/229 reads (12%) | called by muse, mutect2, varscan2
- NOS1AP | c.1115A>G p.Q372R | Missense Mutation (SNP) | VAF 39/513 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- NPVF | c.357C>G p.S119R | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OOSP2 | c.347+2T>A p.X116_splice | Splice Site (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- OPHN1 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2
- OPRPN | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- OR10G4 | c.284G>A p.S95N | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR2B3 | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, varscan2
- OR2C3 | c.613T>A p.F205I | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- OR2G6 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2
- OR4S1 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR5H6 | c.682G>T p.G228* (on ENST00000642105; = p.G212* on NM_001005479.2) | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- OR5T3 | c.784A>T p.I262F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- OR6C74 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PAPPA2 | c.92A>C p.K31T | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); called by muse, mutect2
- PCSK1 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PHYH | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PIGA | c.1348A>G p.I450V | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, varscan2
- PKHD1 | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 36/429 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.522); called by muse, mutect2
- PLCH1 | c.3236G>T p.C1079F (on ENST00000340059 / NM_001130960.2; = p.C1071F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.014); called by muse, mutect2
- PLEC | c.7064A>C p.E2355A (on ENST00000322810 / NM_201380.4; = p.E2245A on NM_000445.5) | Missense Mutation (SNP) | VAF 50/512 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); called by muse, mutect2
- POU3F4 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, varscan2
- PPP1R10 | c.190del p.V64Sfs*16 | Frame Shift Del (DEL) | VAF 11/96 reads (11%) | called by mutect2, pindel*, varscan2
- PPP1R3F | c.493C>A p.R165S | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.739); called by muse, mutect2
- PRR14L | c.3001G>T p.V1001F | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RAX | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RIC8A | c.562G>T p.G188* | Nonsense Mutation (SNP) | VAF 11/202 reads (5%) | called by muse, mutect2
- ROBO3 | c.1712G>T p.S571I | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SEC16A | c.6017G>T p.G2006V | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- SEC16A | c.6016G>T p.G2006C | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SI | c.2585G>A p.C862Y | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- SIGLEC9 | c.1366T>A p.Y456N | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC15A2 | c.673G>T p.G225* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- SLC2A11 | c.193C>T p.L65F (on ENST00000345044 / NM_001024938.4; = p.L72F on NM_030807.5) | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2
- SLC9A6 | c.1300C>T p.L434F | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRRM2 | c.1373C>T p.T458I | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCF25 | c.799G>T p.V267L | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM1 | c.7979C>A p.T2660N | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- TENM3 | c.7877A>C p.Q2626P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- THNSL2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 35/346 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- TLE3 | c.2000A>G p.Y667C | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.814); called by mutect2, varscan2
- TMEM229A | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TTN | c.57448del p.A19150Qfs*22 (on ENST00000591111; = p.A11726Qfs*22 on NM_003319.4) | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- UBL4B | c.401C>A p.A134D | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- URB2 | c.4137G>T p.Q1379H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- VEZF1 | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 44/393 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); called by muse, varscan2
- WNK2 | c.409_423del p.P137_G141del | In Frame Del (DEL) | VAF 10/98 reads (10%) | called by mutect2, pindel, varscan2
- WT1 | c.1316T>C p.F439S | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ZNF347 | c.127A>T p.N43Y | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2
- ALPI | c.1165C>A p.R389= | Silent (SNP) | VAF 17/157 reads (11%) | catalogued as rs138329965; called by muse, mutect2
- AP4B1 | c.1083G>A p.A361= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs779410503, COSV56726814; called by muse, mutect2, varscan2
- ARHGEF12 | c.1422A>T p.P474= | Silent (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- BACE2 | c.216G>A p.A72= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- BRWD3 | c.1956G>A p.R652= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- CAMKK1 | c.534G>A p.G178= | Silent (SNP) | VAF 28/171 reads (16%) | called by muse, mutect2, varscan2
- CCDC14 | c.2649T>C p.D883= (on ENST00000488653; = p.D835= on NM_022757.5) | Silent (SNP) | VAF 15/112 reads (13%) | called by muse, mutect2, varscan2
- CDH22 | c.138G>A p.A46= | Silent (SNP) | VAF 30/269 reads (11%) | called by muse, mutect2, varscan2
- CSF2RB | c.2586C>G p.G862= | Silent (SNP) | VAF 44/295 reads (15%) | called by muse, mutect2, varscan2
- CSMD3 | c.5430A>T p.S1810= (on ENST00000297405 / NM_001363185.1; = p.S1706= on NM_052900.3) | Silent (SNP) | VAF 30/350 reads (9%) | called by muse, mutect2
- CUBN | c.3189C>T p.N1063= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- FARSA | c.174C>G p.T58= | Silent (SNP) | VAF 29/154 reads (19%) | called by muse, mutect2, varscan2
- FBLN2 | c.2496C>A p.G832= | Silent (SNP) | VAF 28/276 reads (10%) | catalogued as rs765299657; called by muse, mutect2
- FER1L6 | c.2748C>A p.A916= | Silent (SNP) | VAF 34/188 reads (18%) | called by muse, mutect2, varscan2
- GC | c.213C>A p.T71= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as rs750307767; called by muse, mutect2
- GPC3 | c.1470G>A p.E490= | Silent (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- GREB1 | c.3918C>T p.T1306= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as rs373285759; called by mutect2, varscan2
- ITSN1 | c.3477G>A p.Q1159= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- KLHL36 | c.1338G>T p.V446= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV50726335; called by muse, mutect2
- KRTAP10-11 | c.657T>A p.P219= | Silent (SNP) | VAF 54/485 reads (11%) | called by muse, mutect2, varscan2
- KY | c.1206G>A p.L402= | Silent (SNP) | VAF 32/215 reads (15%) | catalogued as COSV71016636, COSV71016876; called by muse, mutect2, varscan2
- LAMA1 | c.8751A>G p.T2917= | Silent (SNP) | VAF 37/303 reads (12%) | called by muse, mutect2, varscan2
- MAGEB18 | c.927T>C p.D309= | Silent (SNP) | VAF 19/201 reads (9%) | called by muse, mutect2
- NLRP8 | c.2268G>T p.T756= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as COSV52592625; called by muse, mutect2, varscan2
- PCDHGA9 | c.1383C>G p.L461= | Silent (SNP) | VAF 25/176 reads (14%) | called by muse, mutect2, varscan2
- PHF3 | c.5316A>T p.P1772= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- PLEC | c.8085G>T p.R2695= (on ENST00000322810 / NM_201380.4; = p.R2585= on NM_000445.5) | Silent (SNP) | VAF 74/664 reads (11%) | called by muse, mutect2, varscan2
- PLXNA2 | c.2616A>G p.G872= | Silent (SNP) | VAF 27/161 reads (17%) | called by muse, mutect2, varscan2
- POU3F4 | c.49C>T p.L17= | Silent (SNP) | VAF 30/300 reads (10%) | catalogued as COSV100937184; called by muse, varscan2
- RAB32 | c.39G>A p.A13= | Silent (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
- RBM19 | c.915C>T p.V305= | Silent (SNP) | VAF 26/199 reads (13%) | called by muse, mutect2, varscan2
- SCAF1 | c.1155G>T p.P385= | Silent (SNP) | VAF 23/180 reads (13%) | catalogued as rs368224233; called by muse, mutect2, varscan2
- SCAF8 | c.1992G>T p.P664= | Silent (SNP) | VAF 17/214 reads (8%) | catalogued as COSV63200190; called by muse, mutect2
- SREBF1 | c.3210A>G p.K1070= | Silent (SNP) | VAF 95/457 reads (21%) | called by muse, mutect2, varscan2
- SSTR2 | c.876C>A p.G292= | Silent (SNP) | VAF 18/143 reads (13%) | called by muse, mutect2, varscan2
- SYNDIG1 | c.660C>T p.S220= | Silent (SNP) | VAF 11/93 reads (12%) | called by muse, mutect2, varscan2
- TMEM132D | c.2574C>T p.D858= | Silent (SNP) | VAF 20/262 reads (8%) | catalogued as rs200360275; called by muse, mutect2
- UBQLN1 | c.1662C>T p.L554= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV57409391; called by muse, mutect2
- VIRMA | c.4347A>G p.P1449= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- ZIC3 | c.423C>A p.A141= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- AC011840.1 | n.813C>A | RNA (SNP) | VAF 59/376 reads (16%) | called by muse, mutect2, varscan2
- EIF4A1 | c.345+68A>G | Intron (SNP) | VAF 61/253 reads (24%) | catalogued as rs1260845162; called by muse, mutect2, varscan2
- HERC2P3 | n.1407C>A | RNA (SNP) | VAF 26/355 reads (7%) | called by muse, mutect2
- HTR4 | c.1077-1008A>G | Intron (SNP) | VAF 29/193 reads (15%) | called by muse, mutect2, varscan2
- LTO1 | c.346-1003del | Intron (DEL) | VAF 21/226 reads (9%) | catalogued as rs1565075705; called by mutect2, pindel, varscan2
- MARF1 | c.4814-58G>T | Intron (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- MYBPC1 | c.104-2560G>A | Intron (SNP) | VAF 30/289 reads (10%) | catalogued as COSV62251371; called by muse, mutect2, varscan2
- NFKBIA | c.-35C>A | 5'UTR (SNP) | VAF 6/54 reads (11%) | catalogued as rs1332791939, COSV53755279; called by muse, mutect2
- OR51T1 | chr11:4881855 C>G | 5'Flank (SNP) | VAF 5/38 reads (13%) | called by muse, varscan2
- PDE1C | c.1892-14504C>A | Intron (SNP) | VAF 12/95 reads (13%) | called by muse, varscan2
- PDE4B | c.281+74179A>T | Intron (SNP) | VAF 19/224 reads (8%) | called by muse, mutect2
- PQBP1 | c.179+237G>T | Intron (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- SH3RF3 | c.-244C>G | 5'UTR (SNP) | VAF 40/270 reads (15%) | called by muse, mutect2, varscan2
- SHROOM4 | c.*1257del | 3'UTR (DEL) | VAF 5/46 reads (11%) | called by pindel, varscan2
- SPTA1 | c.6531-21G>C | Intron (SNP) | VAF 18/158 reads (11%) | catalogued as rs778071447; called by muse, mutect2
- TARM1 | chr19:54081338 C>A | 5'Flank (SNP) | VAF 16/139 reads (12%) | called by muse, mutect2, varscan2
- TJP2 | c.61-7287G>A | Intron (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- XIAP | c.*2718del | 3'UTR (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- ZFHX3 | c.-897+3567G>C | Intron (SNP) | VAF 25/194 reads (13%) | called by muse, varscan2
